Surgical pathology report (de-identified scan), TCGA case TCGA-E1-A7YH, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Duke, specimen TCGA-E1-A7YH-01A (Primary Tumor).

Patient: [REDACTED]

Surgical Pathology: Final [REDACTED] Acc# [REDACTED]

Surg Path

CLINICAL HISTORY:

Right temporal brain tumor.

[REDACTED] Low T1 signal non-enhancing right temporal lobe lesion.

GROSS EXAMINATION:

A. "Brain tissue (AF1)", received fresh for frozen section. A 5.0 x 3.0 x 2.5 cm aggregate of brain tissue is received. Representative has been previously submitted as frozen section AF1. The frozen section remnant is submitted in A1. Multiple additional representatives are submitted in A2-A7.

/slides to

INTRA OPERATIVE CONSULTATION:

A. "Brain tissue": AF1- glioma, low grade

MICROSCOPIC EXAMINATION:

Microscopic examination show brain tissue infiltrated by a hypercellular glial neoplasm with moderate cellular pleomorphism and scattered mitoses. Microvascular proliferation and necrosis are not identified. In areas, the tumor cells have prominent perinuclear halos and there is evidence of perineuronal satellitosis.

IMMUNOHISTOCHEMICAL FINDINGS:

Ki-67: PROLIFERATION INDEX OF 3-4%.

DIAGNOSIS:

A. "BRAIN TISSUE" (CRANIOTOMY):

ANAPLASTIC ASTROCYTOMA (WHO GRADE III).
SEE COMMENT.

COMMENT: FISH studies will be reported as an addendum and, given the occasional oligodendroglial features of the tumor cells, 1p/19q testing with be performed and reported as a Cell Imaging test.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [REDACTED]

Printed by:

MIPAA Discrepancy		✓

Source: NCI Genomic Data Commons file a9180f1c-8fb8-497e-9b67-aec3ea8c83b1 (TCGA-E1-A7YH.4E589046-F21D-4822-8243-8805D07E3410.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).